Somatic mutation profile of tumor specimen MMRF_2669_1_BM_CD138pos (aliquot MMRF_2669_1_BM_CD138pos_T1_KHS5U_L14268) from MMRF case MMRF_2669, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 48.4 years (17,672 days).
Specimen MMRF_2669_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 88ab181a-700c-40f3-9815-8efcc0f111cf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2669_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2669_1_PB_WBC_C3_KHS5U_L14404; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02e84d37-afdc-466d-9954-d6e212f0ec63

The open-access MAF lists 85 somatic variants for this specimen: 40 protein-altering or splice-affecting, 9 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 33, 3'UTR 21, Silent 9, Intron 8, 5'UTR 5, Splice Site 3, Nonsense Mutation 3, 5'Flank 1, Frame Shift Del 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDK4 | c.70C>T p.R24C | Missense Mutation (SNP) | VAF 27/166 reads (16%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as rs11547328, CM960267, COSV56984534, COSV56985244; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- NRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 165/669 reads (25%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.525); catalogued as rs121913237, COSV54736383, COSV54736555, COSV54736974; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- BCO2 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 44/407 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs79220685; called by muse, mutect2, varscan2
- BIRC6 | c.9100G>A p.D3034N | Missense Mutation (SNP) | VAF 14/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV70202843; called by muse, mutect2
- CDX4 | c.113C>T p.P38L | Missense Mutation (SNP) | VAF 65/126 reads (52%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV100999144; called by muse, mutect2, varscan2
- CLVS2 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 61/183 reads (33%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.79); catalogued as COSV51561523, COSV51566135; called by muse, mutect2, varscan2
- CSF1R | c.874T>C p.F292L | Missense Mutation (SNP) | VAF 50/362 reads (14%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV53830833; called by muse, mutect2, varscan2
- FBXO28 | c.1042C>T p.R348* | Nonsense Mutation (SNP) | VAF 57/652 reads (9%) | catalogued as COSV64800209; called by muse, mutect2
- GREB1 | c.661G>A p.A221T | Missense Mutation (SNP) | VAF 109/332 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs529473073; called by muse, mutect2, varscan2
- IGLV4-3 | c.164A>G p.Y55C | Missense Mutation (SNP) | VAF 75/152 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs778196121; called by muse, mutect2, varscan2
- MMP20 | c.772C>T p.L258F | Missense Mutation (SNP) | VAF 38/117 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52778862; called by muse, mutect2, varscan2
- MRC2 | c.250C>T p.R84W | Missense Mutation (SNP) | VAF 56/302 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs763220345; called by muse, mutect2, varscan2
- NLGN4X | c.1382C>T p.A461V | Missense Mutation (SNP) | VAF 24/103 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs758529208, COSV52003690; called by muse, mutect2, varscan2
- OLFML2A | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 47/183 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.023); catalogued as rs755291626; called by muse, mutect2, varscan2
- OR8H1 | c.275C>T p.S92F | Missense Mutation (SNP) | VAF 75/362 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs867315106, COSV57293250; called by muse, mutect2, varscan2
- RPL5 | c.3+1G>A p.X1_splice | Splice Site (SNP) | VAF 141/435 reads (32%) | catalogued as COSV59874306; called by muse, mutect2, varscan2
- SCN2A | c.857C>T p.S286F | Missense Mutation (SNP) | VAF 26/248 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.007); catalogued as COSV51838140; called by muse, mutect2, varscan2
- TSHZ1 | c.1963G>A p.E655K (on ENST00000580243 / NM_001308210.2; = p.E610K on NM_005786.6) | Missense Mutation (SNP) | VAF 16/188 reads (9%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.53); catalogued as rs1158623286; called by muse, mutect2
- VPS13C | c.3609C>G p.F1203L (on ENST00000644861 / NM_020821.3; = p.F1160L on NM_017684.5) | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV51145257; called by muse, mutect2, varscan2
- ANKRD35 | c.561-1G>T p.X187_splice | Splice Site (SNP) | VAF 19/261 reads (7%) | called by muse, mutect2
- ARHGAP8 | c.382T>G p.W128G | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated, low confidence (0.34); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- C16orf70 | c.276-1G>T p.X92_splice | Splice Site (SNP) | VAF 58/206 reads (28%) | called by muse, mutect2, varscan2
- CPSF3 | c.863C>T p.A288V | Missense Mutation (SNP) | VAF 7/157 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.187); called by muse, mutect2
- CSNK2A3 | c.11C>A p.P4H | Missense Mutation (SNP) | VAF 57/154 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DHX15 | c.2333G>A p.R778K | Missense Mutation (SNP) | VAF 73/324 reads (23%) | SIFT tolerated (0.41); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- GPC3 | c.1288G>T p.E430* | Nonsense Mutation (SNP) | VAF 53/130 reads (41%) | called by muse, mutect2, varscan2
- HEATR5B | c.2939T>C p.L980P | Missense Mutation (SNP) | VAF 63/519 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- HMMR | c.24_43del p.L8Ffs*11 | Frame Shift Del (DEL) | VAF 28/326 reads (9%) | called by mutect2, pindel
- KIAA1671 | c.72G>T p.K24N | Missense Mutation (SNP) | VAF 128/384 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- MUC4 | c.14720A>T p.E4907V (on ENST00000463781 / NM_018406.7; = p.E671V on NM_004532.6) | Missense Mutation (SNP) | VAF 56/146 reads (38%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PER3 | c.1842G>T p.Q614H | Missense Mutation (SNP) | VAF 14/128 reads (11%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.473); called by muse, mutect2, varscan2
- SHANK2 | c.189C>G p.I63M | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- SIPA1L2 | c.4353A>C p.E1451D | Missense Mutation (SNP) | VAF 76/139 reads (55%) | SIFT tolerated (0.36); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SOS2 | c.531T>A p.D177E | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- SUPT20HL2 | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.12); called by muse, mutect2, varscan2
- TRAF3 | c.1418T>C p.L473P | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TRAF3 | c.1420T>G p.F474V | Missense Mutation (SNP) | VAF 10/148 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- WDFY3 | c.5278C>T p.Q1760* | Nonsense Mutation (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.729G>T p.K243N | Missense Mutation (SNP) | VAF 32/282 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.292); called by muse, mutect2, varscan2
- ZNF511-PRAP1 | c.730C>T p.P244S | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- ACOX2 | c.513T>C p.Y171= | Silent (SNP) | VAF 26/221 reads (12%) | called by muse, mutect2, varscan2
- CAPNS1 | c.141C>T p.G47= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs17879825; called by mutect2, varscan2
- EFNA1 | c.585G>T p.L195= | Silent (SNP) | VAF 131/433 reads (30%) | catalogued as rs756377342; called by muse, mutect2, varscan2
- H2AX | c.378G>A p.G126= | Silent (SNP) | VAF 31/108 reads (29%) | called by muse, mutect2, varscan2
- KPNA7 | c.633G>A p.L211= | Silent (SNP) | VAF 13/182 reads (7%) | catalogued as rs1395412563; called by muse, mutect2
- KRBA1 | c.2880C>T p.P960= | Silent (SNP) | VAF 10/208 reads (5%) | called by muse, mutect2
- MTHFR | c.798G>C p.R266= | Silent (SNP) | VAF 71/350 reads (20%) | called by muse, mutect2, varscan2
- SEMA3A | c.1146C>T p.P382= | Silent (SNP) | VAF 73/223 reads (33%) | called by muse, mutect2, varscan2
- ZNF649 | c.786C>T p.Y262= | Silent (SNP) | VAF 62/167 reads (37%) | catalogued as rs750699673, COSV56816096; called by muse, mutect2, varscan2
- ABCF2 | c.*1153G>A | 3'UTR (SNP) | VAF 17/167 reads (10%) | catalogued as rs901604835; called by muse, mutect2
- ADRA1D | c.*26G>A | 3'UTR (SNP) | VAF 20/179 reads (11%) | called by muse, mutect2, varscan2
- AL121758.1 | c.*1258_*1307del | 3'UTR (DEL) | VAF 62/276 reads (22%) | called by mutect2, pindel
- ARHGAP36 | c.*236C>T | 3'UTR (SNP) | VAF 76/111 reads (68%) | catalogued as rs985054480; called by muse, mutect2, varscan2
- ATP2C1 | c.*1617G>A | 3'UTR (SNP) | VAF 5/70 reads (7%) | called by muse, mutect2
- C8orf34 | c.607+1230C>A | Intron (SNP) | VAF 48/79 reads (61%) | called by muse, mutect2, varscan2
- CAMKMT | c.376+66435C>T | Intron (SNP) | VAF 18/131 reads (14%) | called by muse, mutect2, varscan2
- CCDC50 | c.*4158C>T | 3'UTR (SNP) | VAF 6/76 reads (8%) | called by muse, mutect2
- CD164L2 | c.*216G>A | 3'UTR (SNP) | VAF 69/202 reads (34%) | catalogued as rs375285487; called by muse, mutect2, varscan2
- CLK1 | c.832+85T>C | Intron (SNP) | VAF 11/37 reads (30%) | called by muse, mutect2
- DNAJC21 | c.-161G>A | 5'UTR (SNP) | VAF 9/89 reads (10%) | catalogued as COSV57761008; called by muse, varscan2
- FIBP | c.841-124G>C | Intron (SNP) | VAF 6/40 reads (15%) | called by muse, mutect2, varscan2
- GOPC | c.*1910T>C | 3'UTR (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- HDAC8 | c.738-10884C>T | Intron (SNP) | VAF 3/30 reads (10%) | called by muse, mutect2
- HOXB8 | c.-154C>T | 5'UTR (SNP) | VAF 35/83 reads (42%) | called by muse, mutect2, varscan2
- IGLV3-1 | c.-12G>A | 5'UTR (SNP) | VAF 87/166 reads (52%) | called by muse, mutect2, varscan2
- IRF2BP2 | c.*1303A>C | 3'UTR (SNP) | VAF 10/128 reads (8%) | called by muse, mutect2
- MXRA8 | chr1:1361538 C>A | 5'Flank (SNP) | VAF 82/232 reads (35%) | called by muse, mutect2, varscan2
- NFIB | c.*658G>A | 3'UTR (SNP) | VAF 6/25 reads (24%) | catalogued as rs1309717809; called by muse, mutect2, varscan2
- NSMF | c.*1402G>A | 3'UTR (SNP) | VAF 9/145 reads (6%) | called by muse, mutect2
- NUBP2 | c.600+10G>A | Intron (SNP) | VAF 26/242 reads (11%) | catalogued as rs747144037; called by muse, mutect2, varscan2
- OR52D1 | c.*32dup | 3'UTR (INS) | VAF 87/296 reads (29%) | catalogued as rs575645666; called by mutect2, varscan2
- PADI2 | c.*826G>T | 3'UTR (SNP) | VAF 66/200 reads (33%) | catalogued as rs952490056; called by muse, mutect2, varscan2
- PEX5L | c.*4369C>A | 3'UTR (SNP) | VAF 15/96 reads (16%) | called by muse, mutect2, varscan2
- PLEKHS1 | chr10:113780704 G>A | 3'Flank (SNP) | VAF 23/173 reads (13%) | called by muse, mutect2, varscan2
- SCN4B | c.*270T>C | 3'UTR (SNP) | VAF 105/299 reads (35%) | called by muse, mutect2, varscan2
- SH2B1 | c.-84+104C>A | Intron (SNP) | VAF 4/42 reads (10%) | called by muse, mutect2
- SH3RF3 | c.*864C>T | 3'UTR (SNP) | VAF 49/133 reads (37%) | catalogued as rs759073381; called by muse, mutect2, varscan2
- SLC18A2 | c.1122+119C>T | Intron (SNP) | VAF 4/51 reads (8%) | called by muse, mutect2
- SOX11 | c.*6000G>C | 3'UTR (SNP) | VAF 41/107 reads (38%) | called by muse, mutect2, varscan2
- TMEM92 | c.*1198C>T | 3'UTR (SNP) | VAF 71/213 reads (33%) | called by muse, mutect2, varscan2
- TRHDE | c.*626A>C | 3'UTR (SNP) | VAF 37/71 reads (52%) | called by muse, mutect2, varscan2
- TSC2 | c.-79_-73del | 5'UTR (DEL) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- TYW3 | c.*2012A>T | 3'UTR (SNP) | VAF 20/78 reads (26%) | called by muse, mutect2, varscan2
- WDR72 | c.*1668G>A | 3'UTR (SNP) | VAF 21/88 reads (24%) | called by muse, mutect2, varscan2
- ZNF432 | c.-142_-141del | 5'UTR (DEL) | VAF 21/68 reads (31%) | called by pindel, varscan2
